Somatic mutation profile of tumor specimen C3L-09086-02 (aliquot CPT0492800006) from CPTAC case C3L-09086, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 84.8 years (30,976 days).
Specimen C3L-09086-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Fundus Of Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7f9c2e3-55f0-430e-b25b-384203bb2b4d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09086-31 (Blood Derived Normal), aliquot CPT0492880002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed5e7d0b-749a-4348-b512-0a287889ef1d

The open-access MAF lists 82 somatic variants for this specimen: 62 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 19, Nonsense Mutation 8, Frame Shift Del 6, Splice Region 1, In Frame Del 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C2CD3 | c.184C>T p.R62* | Nonsense Mutation (SNP) | VAF 134/390 reads (34%) | catalogued as rs587777653, CM147608; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1324C>T p.Q442* | Nonsense Mutation (SNP) | VAF 110/187 reads (59%) | catalogued as rs1555687378, COSV61684132; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.405C>A p.C135* | Nonsense Mutation (SNP) | VAF 105/200 reads (53%) | hotspot (GDC flag); catalogued as COSV52665429, COSV52669330, COSV52682693, COSV52815283; called by muse, mutect2, varscan2
- TP53 | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 105/200 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- BPIFB2 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 147/554 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs749996775; called by muse, mutect2, varscan2
- CAMK2B | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 168/470 reads (36%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs201975711, COSV51661444; called by muse, mutect2, varscan2
- FRY | c.4636T>G p.F1546V | Missense Mutation (SNP) | VAF 116/282 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0.054); catalogued as rs901756257; called by muse, mutect2, varscan2
- IKZF3 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 66/309 reads (21%) | catalogued as rs572431209, COSV53099468; called by muse, mutect2, varscan2
- KCNT1 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 16/548 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1456526011, COSV100043695; called by muse, mutect2
- LRP1B | c.5736del p.V1913Wfs*3 | Frame Shift Del (DEL) | VAF 69/216 reads (32%) | catalogued as COSV101254737; called by mutect2, pindel, varscan2
- LUM | c.634T>G p.L212V | Missense Mutation (SNP) | VAF 109/322 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as rs749360955, COSV57127364, COSV57129189; called by muse, mutect2, varscan2
- MAP2K7 | c.811T>C p.S271P | Missense Mutation (SNP) | VAF 116/234 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67609983; called by mutect2, varscan2
- MAP7D2 | c.184C>T p.R62* | Nonsense Mutation (SNP) | VAF 105/149 reads (70%) | catalogued as COSV65526028; called by muse, mutect2, varscan2
- MEPCE | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 189/520 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as COSV99440127; called by muse, varscan2
- MYO9B | c.5191G>A p.E1731K | Missense Mutation (SNP) | VAF 148/265 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1158112387, COSV68277851; called by muse, varscan2
- P2RY8 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 254/949 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as rs762114324, COSV67177276; called by muse, mutect2, varscan2
- PPIL6 | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 60/192 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs372432146, COSV70022277; called by muse, mutect2, varscan2
- PTPRD | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 72/213 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as rs778130827, COSV61937236; called by muse, mutect2, varscan2
- SCGN | c.397T>G p.F133V | Missense Mutation (SNP) | VAF 95/256 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100618911; called by muse, mutect2, varscan2
- SEC24A | c.2231G>C p.G744A | Missense Mutation (SNP) | VAF 85/177 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59746400; called by muse, mutect2, varscan2
- SLC15A3 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 237/728 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs780346061; called by muse, mutect2, varscan2
- SLC35G3 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 201/592 reads (34%) | catalogued as rs762545351; called by muse, mutect2, varscan2
- SLC5A12 | c.115C>T p.R39* | Nonsense Mutation (SNP) | VAF 134/400 reads (34%) | catalogued as rs865879642, COSV54823651; called by muse, mutect2, varscan2
- SLFN14 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 130/345 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1163391239, COSV101334657; called by muse, mutect2, varscan2
- TENM3 | c.6548G>A p.R2183Q | Missense Mutation (SNP) | VAF 127/233 reads (55%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.953); catalogued as rs1414148455; called by muse, mutect2, varscan2
- TGM7 | c.2027C>T p.P676L | Missense Mutation (SNP) | VAF 126/360 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760364994, COSV71772666; called by muse, mutect2, varscan2
- TMEM178B | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 123/369 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1335395690; called by muse, mutect2
- TMPRSS15 | c.820A>T p.T274S | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.08); catalogued as COSV53038605; called by muse, mutect2, varscan2
- TRIM55 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 70/202 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs992697225, COSV52545921; called by muse, mutect2, varscan2
- XKR7 | c.1570C>T p.R524W | Missense Mutation (SNP) | VAF 180/620 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374398061; called by muse, mutect2, varscan2
- ZNF529 | c.1337G>A p.G446D | Missense Mutation (SNP) | VAF 135/220 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61899687; called by muse, mutect2, varscan2
- ALS2 | c.1113G>A p.Q371= | Splice Region (SNP) | VAF 94/222 reads (42%) | called by muse, mutect2, varscan2
- ARHGAP24 | c.1415T>C p.M472T (on ENST00000395184 / NM_001025616.3; = p.M379T on NM_031305.3) | Missense Mutation (SNP) | VAF 146/248 reads (59%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- CDR2 | c.1187C>G p.S396C | Missense Mutation (SNP) | VAF 174/466 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- CEP85L | c.796A>T p.M266L | Missense Mutation (SNP) | VAF 128/315 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSE1L | c.1521G>C p.L507F | Missense Mutation (SNP) | VAF 93/383 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DIS3L | c.1231_1241del p.V411Rfs*31 (on ENST00000319212 / NM_001143688.3; = p.V328Rfs*31 on NM_133375.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 107/363 reads (29%) | called by mutect2, pindel, varscan2
- EP400 | c.7260_7270del p.H2421Vfs*6 | Frame Shift Del (DEL) | VAF 68/315 reads (22%) | called by mutect2, pindel, varscan2
- FLG2 | c.773T>G p.I258S | Missense Mutation (SNP) | VAF 132/518 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIA3 | c.635G>C p.R212T | Missense Mutation (SNP) | VAF 135/195 reads (69%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- GUCY2F | c.3177G>A p.W1059* | Nonsense Mutation (SNP) | VAF 100/140 reads (71%) | called by muse, varscan2
- H2AC12 | c.304_336del p.T102_I112del | In Frame Del (DEL) | VAF 60/342 reads (18%) | called by mutect2, pindel, varscan2
- HNF4G | c.1114G>A p.E372K (on ENST00000354370 / NM_001330561.2; = p.E419K on NM_004133.5) | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- MYCBP2 | c.2806C>A p.H936N (on ENST00000357337; = p.H974N on NM_015057.5) | Missense Mutation (SNP) | VAF 99/300 reads (33%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- NSD3 | c.2540G>A p.C847Y | Missense Mutation (SNP) | VAF 147/439 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NUP188 | c.419T>A p.V140D | Missense Mutation (SNP) | VAF 78/191 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR13G1 | c.585G>A p.M195I | Missense Mutation (SNP) | VAF 127/486 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- PERM1 | c.1618G>A p.A540T | Missense Mutation (SNP) | VAF 212/594 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.359); called by muse, varscan2
- PHF3 | c.3894_3907del p.Y1298* | Frame Shift Del (DEL) | VAF 93/344 reads (27%) | called by mutect2, pindel, varscan2
- POGZ | c.509T>C p.V170A | Missense Mutation (SNP) | VAF 116/377 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- PSD3 | c.143del p.G48Efs*26 | Frame Shift Del (DEL) | VAF 71/241 reads (29%) | called by mutect2, pindel, varscan2
- RAB11FIP4 | c.1090C>G p.L364V | Missense Mutation (SNP) | VAF 123/234 reads (53%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RPL23 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 227/444 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- SNRNP200 | c.1491G>T p.E497D | Missense Mutation (SNP) | VAF 118/318 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TACC2 | c.3869C>T p.S1290F | Missense Mutation (SNP) | VAF 198/529 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- TBX22 | c.756A>C p.K252N | Missense Mutation (SNP) | VAF 137/191 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- TGFBR1 | c.949C>T p.H317Y | Missense Mutation (SNP) | VAF 98/276 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNC | c.3176G>C p.R1059T | Missense Mutation (SNP) | VAF 117/325 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- USP9X | c.7061+2_7061+4del p.X2354_splice | Splice Site (DEL) | VAF 67/106 reads (63%) | called by mutect2, pindel, varscan2
- VPS13C | c.8933T>G p.L2978W (on ENST00000644861 / NM_020821.3; = p.L2935W on NM_017684.5) | Missense Mutation (SNP) | VAF 104/315 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF646 | c.2587C>G p.L863V | Missense Mutation (SNP) | VAF 205/571 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF672 | c.1349del p.S450Lfs*5 | Frame Shift Del (DEL) | VAF 218/560 reads (39%) | called by mutect2, pindel, varscan2
- AKAP4 | c.327T>C p.S109= | Silent (SNP) | VAF 114/183 reads (62%) | called by muse, mutect2, varscan2
- BTNL2 | c.819G>A p.A273= | Silent (SNP) | VAF 106/356 reads (30%) | catalogued as rs987041303; called by muse, mutect2, varscan2
- BX276092.9 | c.618C>T p.D206= | Silent (SNP) | VAF 136/172 reads (79%) | catalogued as rs935929578; called by muse, mutect2, varscan2
- CENPF | c.7266G>A p.L2422= | Silent (SNP) | VAF 76/306 reads (25%) | called by muse, mutect2, varscan2
- CRYBA4 | c.123C>T p.F41= | Silent (SNP) | VAF 147/386 reads (38%) | catalogued as rs924838400, COSV61322867; called by muse, mutect2, varscan2
- EPHA7 | c.2421C>T p.A807= | Silent (SNP) | VAF 112/366 reads (31%) | called by muse, mutect2, varscan2
- GORASP2 | c.459C>T p.I153= | Silent (SNP) | VAF 71/206 reads (34%) | catalogued as COSV52200681; called by muse, mutect2, varscan2
- MALRD1 | c.1729T>C p.L577= | Silent (SNP) | VAF 129/339 reads (38%) | called by muse, mutect2, varscan2
- MTM1 | c.294C>T p.G98= | Silent (SNP) | VAF 89/238 reads (37%) | catalogued as rs781859151; called by muse, mutect2, varscan2
- NR4A2 | c.180C>T p.F60= | Silent (SNP) | VAF 164/475 reads (35%) | called by muse, mutect2, varscan2
- NUP210L | c.1977T>C p.P659= | Silent (SNP) | VAF 92/306 reads (30%) | called by muse, mutect2, varscan2
- OGFOD3 | c.801C>T p.N267= | Silent (SNP) | VAF 105/184 reads (57%) | called by muse, mutect2, varscan2
- OTULINL | c.918A>T p.G306= | Silent (SNP) | VAF 112/243 reads (46%) | called by muse, mutect2, varscan2
- OVOL2 | c.714G>A p.P238= | Silent (SNP) | VAF 163/545 reads (30%) | catalogued as rs376394167, COSV99602311; called by muse, mutect2, varscan2
- POLR3H | c.306C>A p.G102= | Silent (SNP) | VAF 113/1043 reads (11%) | called by muse, mutect2, varscan2
- PTBP2 | c.1392C>T p.T464= (on ENST00000426398 / NM_001300986.2; = p.T456= on NM_021190.4) | Silent (SNP) | VAF 58/204 reads (28%) | called by muse, mutect2, varscan2
- SFT2D2 | c.186A>G p.L62= | Silent (SNP) | VAF 183/430 reads (43%) | called by muse, mutect2, varscan2
- TCHH | c.2937G>A p.E979= | Silent (SNP) | VAF 296/684 reads (43%) | catalogued as rs750011545; called by muse, mutect2, varscan2
- WWC3 | c.588C>T p.G196= | Silent (SNP) | VAF 158/234 reads (68%) | called by muse, varscan2
- SPANXN2 | c.*1T>C | 3'UTR (SNP) | VAF 121/168 reads (72%) | called by muse, varscan2
